Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91V, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91V-01A (Primary Tumor).

[page 1 of 3]
Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Gastroesophageal junction)

1-Inferior paraesophageal lymph node:
Connective and fat tissue uninvolved by neoplasia.

2-Group 5 lymph node:
Connective and fat tissue uninvolved by neoplasia.

3- Group 8A lymph node:
Connective and fat tissue uninvolved by neoplasia.

4- Resection of esophagus + stomach:
Adenocarcinoma with the following features:

Histologic pattern:

Tubular

Mucinous

Per TSS - 100% tubular

Histologic grade:

II - Moderately differentiated

Lauren classification: diffuse type

Largest tumor size: 2.8 cm

Lauren pattern: diffuse

Ulceration: present

Local invasion:

Mucosa

Muscularis Mucosa

Submucosa

Muscularis Propria

Adjacent adipose tissue

Tumor invasion type:

Spiculated

Inflammatory reaction:

Mild

Tumor implant in perivisceral fat tissue:

Not observed

Proximal margin:

Uninvolved by neoplasia

Distal margin:

Uninvolved by neoplasia

Radial margin:

ICD O-3
Adenocarcinoma, tubular
8211/3
path
Adenocarcinoma, tubular +
mucinous
8211/3
8480/3 Code to highest 8480/3

Date Gastroesophageal junction
11/18/14
CLG-D

Per TSS, dx discrepancy from
status TCGA tumor to 100%
tubular.

Diagnosis Discrepancy 100% tubular	☒	☐

[page 2 of 3]
Uninvolved by neoplasia

Neural invasion:

Not observed

Lymphatic invasion:

Present

Blood vessel invasion:

Not observed

Lymph nodes:

Involved by neoplasia: 4 of 10 lymph nodes (4/10)

Capsular invasion: not observed

Lymph node clusters: not observed

Description of lymph nodes:

Periesophageal: 4/5

Lesser curvature: 0/5

5- Esophageal margin:

Focally involved by neoplasia (area of less than 1.0 mm size in adventitia).

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Issue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica) _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report.	Tubular and mucinous	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	100% Tubular	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Case was reviewed based on Top Slide to be sent to BCR	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file c8fa0ea4-57ea-471a-a8e0-aff881ae8422 (TCGA-VQ-A91V.EE0174D4-94B9-4291-9372-F895A7671C9A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).